Somatic mutation profile of tumor specimen TCGA-02-2485-01A (aliquot TCGA-02-2485-01A-01W-0837-08) from TCGA case TCGA-02-2485, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,494 days).
Specimen TCGA-02-2485-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c1abd20-3357-4046-8f6f-93be3d8adb45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-2485-10A (Blood Derived Normal), aliquot TCGA-02-2485-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67fe3e80-70c3-4452-a3d7-0851e010ed9e

The open-access MAF lists 67 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Del 4, In Frame Del 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 1030/1088 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 207/503 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 50/121 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- ARHGEF5 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 233/1797 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV50218152, COSV99283276; called by muse, mutect2, varscan2
- CD300A | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60409780; called by muse, mutect2, varscan2
- CHRM2 | c.1126A>G p.K376E | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV57768695; called by muse, mutect2, varscan2
- COLQ | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 345/866 reads (40%) | catalogued as rs760669036, CM030023, COSV67524375, COSV67526240; called by muse, mutect2, varscan2
- CYP2C8 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 436/516 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs777501435, COSV64876497; called by muse, mutect2, varscan2
- EEF2 | c.1193T>G p.I398S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV58578947; called by muse, mutect2, varscan2
- EMILIN3 | c.1380dup p.W461Vfs*31 | Frame Shift Ins (INS) | VAF 10/78 reads (13%) | catalogued as rs759858342; called by mutect2, varscan2
- EPHB2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); catalogued as rs763188025, COSV65861269; called by muse, mutect2, varscan2
- EXOC3L2 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs202169742; called by muse, mutect2, varscan2
- FLG | c.7598G>A p.R2533H | Missense Mutation (SNP) | VAF 354/960 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs754603159, COSV64239282; called by muse, mutect2
- HECA | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV62768915; called by muse, mutect2, varscan2
- HEPH | c.3421C>T p.R1141C (on ENST00000343002; = p.R874C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs781742782, COSV57961166; called by muse, mutect2
- HYDIN | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs368636754, COSV59253098; called by muse, mutect2, varscan2
- IGHG2 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 221/286 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765439103; called by mutect2, varscan2
- IRGC | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs770459179, COSV54983429; called by muse, mutect2, varscan2
- ITGAM | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54934571; called by muse, mutect2, varscan2
- LGSN | c.134T>G p.V45G | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV65726619; called by muse, mutect2, varscan2
- LILRB2 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1482616572, COSV58744257, COSV58747833; called by muse, mutect2, varscan2
- LRWD1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371342787; called by muse, mutect2, varscan2
- MAML1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV52984202, COSV52986426; called by muse, mutect2, varscan2
- MSN | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 68/74 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV64303643; called by muse, mutect2, varscan2
- MUC16 | c.34760C>T p.T11587M | Missense Mutation (SNP) | VAF 162/534 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs763078522, COSV67455495; called by muse, mutect2, varscan2
- NEURL1 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63914091; called by muse, mutect2, varscan2
- NOP2 | c.440A>C p.D147A (on ENST00000322166 / NM_001258308.2; = p.D143A on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV58897285; called by muse, mutect2, varscan2
- OR5M11 | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV101602010, COSV73141686; called by muse, mutect2, varscan2
- OR7E24 | c.154A>G p.M52V | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV71702164; called by muse, mutect2, varscan2
- PIK3CA | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55902181; called by muse, mutect2, varscan2
- POM121L12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692577; called by muse, mutect2, varscan2
- POM121L12 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 71/510 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs749141757, COSV68692580, COSV68693810; called by muse, mutect2, varscan2
- PRPS2 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 156/181 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV66126143; called by muse, mutect2, varscan2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- SCN3A | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 82/249 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV51805642; called by muse, mutect2, varscan2
- SEPTIN4 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV58727456; called by muse, mutect2, varscan2
- SLCO6A1 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs139495343, COSV65808002; called by muse, varscan2
- THEG | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs575728371, COSV61073521; called by muse, mutect2, varscan2
- UVRAG | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 378/859 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as rs200253982, COSV62105439; called by muse, mutect2, varscan2
- VPS41 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56069379; called by muse, mutect2, varscan2
- WNT3 | c.181A>G p.N61D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56644457; called by muse, mutect2, varscan2
- ZNF804A | c.2390G>A p.R797K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV56441663; called by muse, mutect2, varscan2
- AMPD2 | c.2273del p.K758Rfs*63 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- BMS1 | c.2525_2527del p.E842del | In Frame Del (DEL) | VAF 46/187 reads (25%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.388_390del p.S130del | In Frame Del (DEL) | VAF 237/1237 reads (19%) | called by mutect2, pindel, varscan2
- ROBO1 | c.20_21del p.P7Lfs*25 | Frame Shift Del (DEL) | VAF 91/336 reads (27%) | called by mutect2, pindel, varscan2
- RYR2 | c.14412G>A p.M4804I | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- SBF1 | c.5335del p.Q1779Sfs*23 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- WNT2B | c.766_767del p.S256Rfs*7 (on ENST00000369684 / NM_024494.3; = p.S237Rfs*7 on NM_004185.4) | Frame Shift Del (DEL) | VAF 79/213 reads (37%) | called by pindel, varscan2
- ATP13A1 | c.3552G>A p.A1184= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs773216044, COSV52284097; called by muse, mutect2, varscan2
- CACNG3 | c.399C>T p.N133= | Silent (SNP) | VAF 79/229 reads (34%) | catalogued as rs147734423; called by muse, mutect2, varscan2
- COL6A3 | c.8358C>T p.F2786= | Silent (SNP) | VAF 111/211 reads (53%) | catalogued as rs113423040, COSV55084540, COSV55108770; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK8 | c.267C>T p.D89= | Silent (SNP) | VAF 138/314 reads (44%) | catalogued as rs770313916, COSV66633563; ClinVar: benign; called by muse, mutect2, varscan2
- DSP | c.6396G>A p.G2132= | Silent (SNP) | VAF 47/110 reads (43%) | catalogued as COSV65792019; called by muse, mutect2, varscan2
- EPHA8 | c.2275C>A p.R759= | Silent (SNP) | VAF 2/12 reads (17%) | catalogued as COSV51262610; called by muse, mutect2
- IGKV3D-20 | c.261G>T p.G87= | Silent (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- JARID2 | c.3687C>T p.P1229= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs200263166; called by muse, mutect2, varscan2
- MYO19 | c.2133T>C p.I711= (on ENST00000614623 / NM_001163735.1; = p.I511= on NM_025109.5) | Silent (SNP) | VAF 39/231 reads (17%) | called by mutect2, varscan2
- NOD1 | c.675C>T p.D225= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs150842987, COSV56111071; called by muse, mutect2, varscan2
- NYAP2 | c.825C>A p.I275= | Silent (SNP) | VAF 148/339 reads (44%) | catalogued as COSV56001683, COSV56004371; called by muse, varscan2
- NYAP2 | c.846C>T p.D282= | Silent (SNP) | VAF 148/316 reads (47%) | catalogued as COSV56001691; called by muse, varscan2
- PCDHA12 | c.2202G>A p.P734= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV56488495, COSV99166277; called by muse, mutect2, varscan2
- REEP2 | c.678G>A p.A226= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs373069993; called by muse, mutect2, varscan2
- SHISAL1 | c.216C>T p.N72= | Silent (SNP) | VAF 126/234 reads (54%) | catalogued as rs373946331, COSV66987663; called by muse, varscan2
- ZNF681 | c.858A>G p.E286= | Silent (SNP) | VAF 92/305 reads (30%) | catalogued as COSV68073922; called by muse, mutect2, varscan2
- MMP10 | c.*2C>T | 3'UTR (SNP) | VAF 88/208 reads (42%) | catalogued as rs747206561, COSV99666835; called by muse, mutect2, varscan2
- SSX9P | n.71A>G | RNA (SNP) | VAF 34/816 reads (4%) | called by muse, mutect2
